Somatic mutation profile of tumor specimen TCGA-G3-A5SK-01A (aliquot TCGA-G3-A5SK-01A-11D-A27I-10) from TCGA case TCGA-G3-A5SK, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 58.4 years (21,320 days).
Specimen TCGA-G3-A5SK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f801b54f-c21c-46f0-84c5-c13e1d303211.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A5SK-10A (Blood Derived Normal), aliquot TCGA-G3-A5SK-10A-01D-A27I-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58a4e8ad-8bca-4e25-99e4-752e0708583b

The open-access MAF lists 93 somatic variants for this specimen: 73 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 19, Frame Shift Del 4, Nonsense Mutation 3, In Frame Del 2, Splice Site 2, In Frame Ins 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP3 | c.230A>T p.Q77L | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60485010; called by muse, mutect2, varscan2
- ADAM29 | c.2108C>G p.P703R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV63661544; called by muse, mutect2, varscan2
- ADAMTS14 | c.2123G>T p.G708V | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64600390; called by muse, mutect2
- ADCY3 | c.1647G>T p.E549D | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV53165263; called by muse, mutect2, varscan2
- ALB | c.1214T>C p.V405A | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV55736448; called by muse, mutect2, varscan2
- ALKBH5 | c.995A>T p.D332V | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as COSV67686812; called by muse, mutect2, varscan2
- ARHGAP32 | c.5960A>G p.H1987R (on ENST00000310343 / NM_001378025.1; = p.H1638R on NM_014715.4) | Missense Mutation (SNP) | VAF 25/259 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as rs752941537, COSV59844536; called by muse, mutect2
- ARID2 | c.2544dup p.A849Sfs*102 | Frame Shift Ins (INS) | VAF 90/268 reads (34%) | catalogued as COSV57611261; called by mutect2, varscan2
- BPIFB2 | c.1328T>C p.V443A | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV50063431; called by muse, mutect2, varscan2
- BRWD3 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV64745155; called by muse, mutect2
- CACNA2D3 | c.3265T>G p.F1089V | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV55522273; called by muse, mutect2
- CCT4 | c.347T>G p.L116R | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66701174; called by muse, mutect2, varscan2
- CD93 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.572); catalogued as COSV55663905; called by muse, mutect2, varscan2
- CDH7 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV59882930; called by muse, mutect2, varscan2
- CEP68 | c.2039C>G p.S680C | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV53123871; called by muse, mutect2, varscan2
- CFAP47 | c.4850T>C p.V1617A | Missense Mutation (SNP) | VAF 48/63 reads (76%) | SIFT tolerated (0.84); PolyPhen benign (0.031); catalogued as COSV57972049; called by muse, mutect2, varscan2
- CNTNAP5 | c.2875C>A p.H959N | Missense Mutation (SNP) | VAF 92/308 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV70477613, COSV70486511; called by muse, varscan2
- CYP46A1 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55893091; called by muse, mutect2, varscan2
- DCDC1 | c.912G>A p.M304I | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV60836620; called by muse, mutect2
- DMRTA1 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 37/116 reads (32%) | catalogued as rs558506579, COSV57923891, COSV57924083; called by mutect2, varscan2
- DNAH17 | c.11368G>T p.D3790Y | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV67750948; called by muse, mutect2, varscan2
- DNAH9 | c.9003G>T p.E3001D | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV52339639, COSV99306710; called by muse, mutect2, varscan2
- EPB41L2 | c.2981A>G p.H994R | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61353903; called by muse, mutect2, varscan2
- EXPH5 | c.2746C>A p.P916T | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.571); catalogued as COSV56199864, COSV56204621; called by muse, mutect2, varscan2
- FAM166B | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV63427897; called by muse, mutect2, varscan2
- FFAR2 | c.358T>G p.S120A | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1170543638, COSV55831944; called by muse, mutect2, varscan2
- GABRQ | c.815T>C p.V272A | Missense Mutation (SNP) | VAF 156/406 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.413); catalogued as COSV64781191; called by muse, mutect2, varscan2
- HERC2 | c.9604C>G p.L3202V | Missense Mutation (SNP) | VAF 74/257 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55312902; called by muse, mutect2, varscan2
- IKBIP | c.180-2A>T p.X60_splice | Splice Site (SNP) | VAF 14/33 reads (42%) | catalogued as COSV54488952; called by muse, mutect2, varscan2
- IRAK3 | c.653+1G>T p.X218_splice | Splice Site (SNP) | VAF 26/83 reads (31%) | catalogued as COSV54160094; called by muse, mutect2, varscan2
- ISL1 | c.665C>A p.P222H | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57932753, COSV57934438; called by muse, mutect2, varscan2
- KATNIP | c.3689G>A p.G1230D | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55175559; called by muse, mutect2
- KCTD16 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV72577197; called by muse, mutect2, varscan2
- KDM5C | c.2267T>A p.L756H | Missense Mutation (SNP) | VAF 144/231 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64763432; called by muse, mutect2, varscan2
- KIAA0232 | c.2090T>A p.F697Y | Missense Mutation (SNP) | VAF 78/228 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV56923882; called by muse, mutect2, varscan2
- MAP3K9 | c.1217T>C p.I406T | Missense Mutation (SNP) | VAF 87/268 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1389314441, COSV67120365; called by muse, mutect2, varscan2
- MEGF6 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs375609074; called by muse, mutect2, varscan2
- MIA3 | c.3185A>G p.H1062R | Missense Mutation (SNP) | VAF 90/393 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs766911071, COSV60510684; called by muse, mutect2, varscan2
- MIGA2 | c.341G>C p.S114T | Missense Mutation (SNP) | VAF 8/234 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1482165331, COSV99477972; called by muse, mutect2
- MTRR | c.1486G>C p.V496L (on ENST00000264668; = p.V469L on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); catalogued as COSV52942271; called by muse, mutect2
- NOP56 | c.356C>G p.A119G | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV61389198; called by muse, mutect2, varscan2
- NSD1 | c.6719C>A p.S2240* | Nonsense Mutation (SNP) | VAF 32/84 reads (38%) | catalogued as COSV61772428; called by muse, mutect2, varscan2
- NXPH2 | c.721G>C p.D241H | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55640646; called by muse, mutect2, varscan2
- OR2M7 | c.325G>C p.G109R | Missense Mutation (SNP) | VAF 178/391 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV58738257, COSV58738829; called by muse, mutect2, varscan2
- OR5T1 | c.274A>G p.K92E | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV100478697, COSV57301956; called by muse, mutect2, varscan2
- PCDH11Y | c.2584A>T p.I862F (on ENST00000400457 / NM_032973.2; = p.I851F on NM_032971.3) | Missense Mutation (SNP) | VAF 198/335 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV99293211; called by muse, varscan2
- PLCB4 | c.1253A>G p.Y418C | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1250769070, COSV53796130; called by muse, mutect2, varscan2
- RXFP3 | c.1215G>A p.W405* | Nonsense Mutation (SNP) | VAF 42/104 reads (40%) | catalogued as COSV57504542; called by muse, mutect2, varscan2
- RYR2 | c.8237T>C p.I2746T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV63670530; called by muse, mutect2, varscan2
- S100A4 | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.226); catalogued as COSV62876558; called by muse, mutect2
- SDK1 | c.452A>T p.E151V | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.809); catalogued as rs762716721, COSV67360020; called by muse, mutect2, varscan2
- SH3RF1 | c.668A>C p.K223T | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52919034; called by muse, mutect2, varscan2
- SLC26A4 | c.1961C>T p.P654L | Missense Mutation (SNP) | VAF 78/241 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as COSV55914975; called by muse, mutect2, varscan2
- SLC27A3 | c.1453G>C p.A485P (on ENST00000271857; = p.A357P on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55162608; called by muse, mutect2
- SLC39A9 | c.871C>G p.L291V | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.802); catalogued as COSV50362164; called by muse, mutect2, varscan2
- SLITRK2 | c.1471T>A p.F491I | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59423738; called by muse, mutect2, varscan2
- TENT5A | c.1043A>G p.E348G | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV60787507; called by muse, mutect2, varscan2
- TRIM15 | c.739A>C p.M247L | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV64989142; called by muse, mutect2, varscan2
- TRPV1 | c.1601T>G p.L534R | Missense Mutation (SNP) | VAF 78/153 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV51516324; called by muse, mutect2, varscan2
- TXK | c.1371G>T p.W457C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51913353; called by muse, mutect2, varscan2
- UMODL1 | c.3502C>A p.P1168T (on ENST00000408910 / NM_001004416.2; = p.P1296T on NM_173568.3) | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV68569398; called by muse, mutect2, varscan2
- WNK2 | c.6842G>T p.R2281L | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs149156267, COSV52943662, COSV99945197; called by muse, mutect2, varscan2
- ZACN | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 66/215 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV58035289; called by muse, mutect2, varscan2
- ZBTB40 | c.3089C>A p.P1030H | Missense Mutation (SNP) | VAF 211/656 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65144799; called by muse, mutect2, varscan2
- ZMIZ2 | c.665C>G p.S222C | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV54806525, COSV99537166; called by muse, mutect2, varscan2
- ZNF287 | c.261A>C p.Q87H | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67688208; called by muse, mutect2
- BIRC2 | c.777_779dup p.S260dup | In Frame Ins (INS) | VAF 17/45 reads (38%) | called by mutect2, pindel, varscan2
- CYP2E1 | c.38_61del p.W13_V20del | In Frame Del (DEL) | VAF 17/39 reads (44%) | called by mutect2, varscan2
- DCDC1 | c.4575_4580del p.K1526_S1527del (on ENST00000597505 / NM_001367979.1; = p.K633_S634del on NM_020869.3) | In Frame Del (DEL) | VAF 19/113 reads (17%) | called by mutect2, pindel, varscan2
- ESRP1 | c.877del p.R293Gfs*24 | Frame Shift Del (DEL) | VAF 74/272 reads (27%) | called by mutect2, pindel, varscan2
- GJA8 | c.1007del p.P336Rfs*21 | Frame Shift Del (DEL) | VAF 32/185 reads (17%) | called by mutect2, pindel, varscan2
- MSRB1 | c.15_39del p.S5Rfs*55 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel
- U2SURP | c.1561del p.T521Qfs*5 | Frame Shift Del (DEL) | VAF 70/242 reads (29%) | called by mutect2, pindel, varscan2
- CACNA1S | c.816C>T p.I272= | Silent (SNP) | VAF 156/380 reads (41%) | catalogued as COSV62937374; called by muse, mutect2, varscan2
- CWC25 | c.1257G>A p.E419= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as rs1323613499; called by muse, mutect2, varscan2
- CWH43 | c.1854A>G p.R618= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs1465383784, COSV56936967; called by muse, mutect2, varscan2
- FAT3 | c.9063T>C p.D3021= | Silent (SNP) | VAF 63/205 reads (31%) | catalogued as COSV53087263; called by muse, mutect2, varscan2
- FKBP10 | c.810A>G p.L270= | Silent (SNP) | VAF 7/146 reads (5%) | catalogued as rs782604150, COSV58635401; called by muse, mutect2
- GP9 | c.531T>C p.D177= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV56623823; called by muse, mutect2
- HOXD12 | c.114G>C p.A38= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV66832386, COSV66832421; called by muse, mutect2, varscan2
- MTARC2 | c.471C>T p.G157= | Silent (SNP) | VAF 137/270 reads (51%) | catalogued as rs771147912, COSV63765177; called by muse, mutect2
- NEXMIF | c.2304A>T p.S768= | Silent (SNP) | VAF 61/84 reads (73%) | catalogued as COSV50023662; called by muse, mutect2, varscan2
- PLG | c.963A>G p.E321= | Silent (SNP) | VAF 24/229 reads (10%) | catalogued as COSV51981467; called by muse, mutect2
- PTPRZ1 | c.4116G>C p.G1372= | Silent (SNP) | VAF 60/222 reads (27%) | catalogued as COSV101099733, COSV66432394; called by muse, mutect2, varscan2
- SDC2 | c.579G>A p.K193= | Silent (SNP) | VAF 36/130 reads (28%) | catalogued as COSV56226443; called by muse, varscan2
- SPTBN5 | c.6465C>T p.T2155= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as COSV58017827; called by muse, mutect2, varscan2
- TJP2 | c.1005G>T p.T335= | Silent (SNP) | VAF 43/110 reads (39%) | catalogued as COSV55263727; called by muse, mutect2, varscan2
- USF3 | c.6711A>G p.L2237= | Silent (SNP) | VAF 59/174 reads (34%) | catalogued as COSV57070771; called by muse, mutect2, varscan2
- USH2A | c.10335A>G p.S3445= | Silent (SNP) | VAF 132/464 reads (28%) | catalogued as COSV56339944; called by muse, mutect2, varscan2
- WDPCP | c.1143A>G p.S381= | Silent (SNP) | VAF 7/97 reads (7%) | catalogued as COSV55415091; called by muse, mutect2
- WDR86 | c.360G>C p.R120= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV57838712; called by muse, mutect2, varscan2
- ZSWIM3 | c.1773C>G p.L591= | Silent (SNP) | VAF 99/325 reads (30%) | catalogued as COSV54845582, COSV54845681; called by muse, mutect2, varscan2
- MIR374B | n.47A>C | RNA (SNP) | VAF 95/111 reads (86%) | called by muse, mutect2, varscan2
